Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A62N, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A62N-01A (Primary Tumor).

[page 1 of 4]
Pathology Report:

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Right pelvic lymph nodes; lymphadenectomy:

- Eighteen lymph nodes, no tumor (0/18).

B. Left pelvic lymph nodes; lymphadenectomy:

- Eight lymph nodes, no tumor (0/8).

C. Urinary bladder, prostate, bilateral vas deferens;
cystoprostatectomy:

- Bladder with high grade urothelial carcinoma with sarcomatoid change, invading thru the muscularis propria and into the perivesical fat, see pathologic parameters.
- Prostate with high grade prostatic intraepithelial neoplasia.
- One perivesical lymph node, no tumor (0/1).
- All specimen margins, free of tumor.

D. Right distal ureter; excision:

- Portion of ureter, no tumor.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Invasive urothelial carcinoma, with spindle cell sarcomatoid change (25%).
2. Grade of tumor: High grade.
3. Depth of invasion: Extravesicular soft tissue (macroscopic).
4. Tumor distribution: Solitary, 4.0 cm, right lateral, anterior and posterior walls.
5. Ureteral margins: Negative for tumor.
6. Distal urethral margin: Negative for tumor.
7. Soft tissue margin or serosa: Negative for tumor.
8. Lymph nodes: Negative for tumor (0/27).
9. pTNM: pT3b,N0,MX.

Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

path ICD-O-3
Carcinoma, urothelial, spindle cell
sarcomatoid 8/22/13

CGCF Carcinoma, urothelial NOS 8/20/13

Site: path Bladder Wall NOS C67.9
CGCF Lateral wall of bladder C67.2
9/24/13

[page 2 of 4]
Interpretation performed by the Attending Pathologist and reviewed with the

Clinical History:

Patient is a year-old male with urothelial carcinoma undergoing radical cystectomy and prostatectomy.

Specimens Received:

- A: Right pelvic lymph node
- B: Left pelvic lymph node
- C: Bladder, prostate, bilateral vas deferens
- D: Right distal ureter

Gross Description:

The specimens are received in four containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "right pelvic lymph node". Received fresh and placed in formalin are multiple yellow-tan fibroadipose tissue fragments forming an aggregate which measures 7 x 4.6 x 1.8 cm. The specimen is dissected to reveal 16 lymph node candidates ranging from 0.3-7.0 cm in greatest dimension. They are submitted as A1-A9.

Block summary:

- A1: 7 lymph node candidates
- A2: 4 lymph node candidates
- A3: 4 lymph node candidates
- A4-A9: 1 lymph node candidate, serially sectioned

B. The second container is additionally identified as, "left pelvic lymph node". Received fresh and placed in formalin are multiple yellow-tan, soft fibroadipose tissue fragments forming in aggregate measuring 7 x 3 x 0.6 cm. The specimen is dissected to reveal 7 lymph node candidates measuring 0.5-7 cm in greatest dimension. They are submitted as B1-B8.

Block summary:

- B1: 5 lymph node candidates
- B2-B3: 1 lymph node candidate, serially sectioned
- B4-B8: 1 lymph node candidate, serially sectioned

C. The third container is additionally identified as, "bladder, prostate, bilateral vas deferens". Received fresh and placed in formalin is a 351.5 g, 18 x 9.5 x 4.5 cm cystoprostatectomy specimen consisting of a 8.5 x 8.5 x 4.3 cm bladder with attached mesenteric fat and a 4.3 x 3.5 x 2.8 cm prostate. The

[page 3 of 4]
anterior aspect of the prostate is focally disrupted. The right seminal vesicles measure 1.8 x 1.2 x 0.7 cm and right vas deferens measures 1.5 x 0.4 cm. The left seminal vesicles measures 1.7 x 1.4 x 0.7 cm and left vas deferens measures 1.5 x 0.5 cm. The right ureteral stump measures 2 x 0.5 cm, the left measures 1.5 x 0.4 cm, and each demonstrates an intact, patent lumen.

The right half of the prostate and bladder is inked blue and the left half is inked black. The bladder and prostate are opened anteriorly along the urethra. The outer surface of the prostate is red-brown and shaggy. The prostate is sectioned into 6 slices and demonstrates rubbery, pink-tan, peri-urethral nodularity with no discrete masses or indurations. Approximately 60% of the prostate is submitted.

The opened bladder reveals a 4 x 3.2 cm rough, yellow-brown, friable ulceration located in the right lateral, the right anterior, and the right posterior wall. The deep margin adjacent to the ulceration is inked black. On cut section, the 4 x 3.2 x 1.5 cm white-tan, ill-defined firm area of induration is underneath and admixed with the ulceration, extends into and through the muscularis propria into the perivesical fat and is 0.3 cm from the deep margin. The surrounding bladder mucosa is edematous, wrinkled, pink-tan with a uniform 0.1-0.2 cm wall thickness.

Representative sections are submitted as follows:

C1: Distal prostatic urethral margin

C2: Right and left ureter resection margins

C3: Apex of prostate

C4-C6: Representative right lobe of prostate from apex to base

C7-C9: Representative left lobe of prostate submitted from apex to base

C10: Uninvolved bladder mucosa posterior wall

C11 Uninvolved bladder mucosa dome

C12: Uninvolved bladder mucosa anterior wall

C13: Uninvolved bladder mucosa trigone

C14: Uninvolved bladder mucosa left lateral wall

C15: Uninvolved bladder mucosa right lateral wall

C16-C22: Bladder mass/Ulceration (C19-C20: in tandem, C21: closest to deep margin)

C23-C24: Additional ureter

D. The fourth container is additionally identified as, "right distal ureter".

Received fresh in place in formalin

is an unoriented, 1.1 cm long pink-tan and is white-tan, ureter with a pinpoint diameter. There is a suture marking one end, which is inked blue and the opposite end is inked black. The central portion of the ureter is not inked and the specimen is trisected and entirely submitted as D1.

[page 4 of 4]
Diagnosis Discrepancy pw 4/5/13 25% spindle cell		☒
Reviewed: KMI	Date Reviewed: 4/12/13	

Source: NCI Genomic Data Commons file d2aafc01-0651-4a0b-89e8-34873c739d3b (TCGA-FD-A62N.16D179ED-9A97-4CB8-BC78-0D4D20AE6B8E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).